Somatic mutation profile of tumor specimen TCGA-EA-A97N-01A (aliquot TCGA-EA-A97N-01A-11D-A387-09) from TCGA case TCGA-EA-A97N, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 38.3 years (13,984 days).
Specimen TCGA-EA-A97N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab2a0bcb-33e4-407a-8274-3cd80a8f3cf1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A97N-10A (Blood Derived Normal), aliquot TCGA-EA-A97N-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae29998a-1ecc-4123-a8c0-e0416f8250a2

The open-access MAF lists 128 somatic variants for this specimen: 85 protein-altering or splice-affecting, 42 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 42, Nonsense Mutation 10, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99939784; called by muse, mutect2, varscan2
- AJAP1 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs567462755, COSV100981971, COSV65449197; called by muse, mutect2, varscan2
- ANKRD24 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs377020129; called by muse, mutect2, varscan2
- ASXL3 | c.2527G>C p.D843H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV99323052; called by muse, mutect2, varscan2
- ATP10D | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.161); catalogued as COSV99905031; called by muse, mutect2, varscan2
- ATP6V0D2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99571241; called by muse, mutect2, varscan2
- ATR | c.6286G>C p.D2096H | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100637613; called by muse, mutect2
- CA1 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99809963; called by muse, mutect2, varscan2
- CEP20 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99739621, COSV99739870; called by muse, mutect2, varscan2
- CHD7 | c.8188G>A p.A2730T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs757707495, COSV101417957; called by muse, mutect2, varscan2
- CHRNA5 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100213750; called by muse, mutect2, varscan2
- CNOT10 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1444335593; called by muse, mutect2
- CSMD1 | c.4633G>A p.D1545N (on ENST00000520002; = p.D1544N on NM_033225.6) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100142642; called by muse, mutect2, varscan2
- DCAF4L2 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs780860993, COSV100150443; called by muse, mutect2, varscan2
- DNAH8 | c.3052C>T p.R1018C | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs200239803; called by muse, mutect2, varscan2
- EIF4G1 | c.4189C>T p.R1397* (on ENST00000346169 / NM_198241.3; = p.R1202* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 31/188 reads (16%) | catalogued as COSV59989834; called by muse, mutect2, varscan2
- F2RL1 | c.945G>C p.K315N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.913); catalogued as COSV99688630; called by mutect2, varscan2
- FANCM | c.2491G>T p.E831* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as COSV99950328; called by muse, mutect2, varscan2
- FLG | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV64249223; called by muse, mutect2, varscan2
- FMO3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs866502499, COSV63006994; called by muse, mutect2
- FOXM1 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as rs760399764, COSV100700782; called by muse, mutect2, varscan2
- GASK1B | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV56710775; called by muse, mutect2, varscan2
- HCN2 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV52113965; called by muse, mutect2
- HDAC6 | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1557023103, COSV100490522; called by muse, mutect2, varscan2
- HECW2 | c.4279C>T p.R1427C | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53671221; called by muse, mutect2, varscan2
- HK2 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749170805, COSV51876404; called by muse, mutect2, varscan2
- HPSE2 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV100984758, COSV65179602; called by muse, mutect2
- HSPA14 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as rs199812378, COSV101000631; called by muse, mutect2, varscan2
- IMPA1 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99808745; called by muse, mutect2, varscan2
- KIF21B | c.4268C>T p.S1423L (on ENST00000422435 / NM_001252100.2; = p.S1410L on NM_017596.4) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1191391325, COSV59754665; called by muse, mutect2
- LAMB1 | c.1714G>C p.E572Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99739714; called by muse, mutect2
- LPA | c.5072C>T p.T1691M | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs757188741, COSV60314570; called by muse, mutect2, varscan2
- MAF1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV100075248; called by muse, mutect2
- MAGEB3 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV100854588, COSV100854764; called by muse, mutect2, varscan2
- MST1R | c.112C>G p.R38G | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV99617543; called by muse, mutect2, varscan2
- MTX2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99980688; called by muse, mutect2, varscan2
- MUC16 | c.27937C>T p.P9313S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.021); catalogued as rs1366931569, COSV101197794; called by muse, mutect2
- MUC17 | c.8386G>A p.E2796K | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as rs1437108359, COSV100071364; called by muse, mutect2, varscan2
- NECAB2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs200006978, COSV59420472; called by muse, mutect2, varscan2
- NFE2L3 | c.1947_1948del p.D651* | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as rs1306406908; called by mutect2, pindel, varscan2
- NUSAP1 | c.1026G>C p.L342F | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99530687; called by muse, mutect2, varscan2
- OR14I1 | c.901A>G p.R301G | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100700420; called by muse, mutect2, varscan2
- P2RX5 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.046); catalogued as COSV99835605; called by muse, mutect2, varscan2
- PCDHB6 | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 27/89 reads (30%) | catalogued as rs1345534729, COSV50694889; called by muse, mutect2, varscan2
- PDE3A | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs764097682, COSV100761579; called by muse, mutect2, varscan2
- PKHD1L1 | c.5737G>A p.E1913K | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV101005206; called by muse, mutect2, varscan2
- PLCH1 | c.3917G>A p.G1306E (on ENST00000340059 / NM_001130960.2; = p.G1298E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.015); catalogued as COSV100395413; called by muse, mutect2, varscan2
- PLCH1 | c.3916G>A p.G1306R (on ENST00000340059 / NM_001130960.2; = p.G1298R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV100395415; called by muse, mutect2, varscan2
- PML | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1026561797, COSV51454119; called by muse, mutect2, varscan2
- PNMA8B | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs755981121, COSV66538219; called by muse, mutect2, varscan2
- PODNL1 | c.1514G>A p.W505* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99582740; called by muse, mutect2, varscan2
- PRAMEF4 | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99339407, COSV99339676; called by muse, mutect2, varscan2
- PRICKLE1 | c.2078G>A p.R693K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100453395, COSV58208793; called by muse, mutect2
- PTPN22 | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100703353, COSV63084162, COSV63084952; called by muse, mutect2
- RASGRF1 | c.3686G>T p.R1229L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101174268, COSV67249900; called by muse, mutect2, varscan2
- RBM4B | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as rs1411291283, COSV100026333, COSV59496482; called by muse, mutect2, varscan2
- RIC8A | c.1309G>A p.E437K (on ENST00000526104 / NM_001286134.1; = p.E443K on NM_021932.5) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV100291385; called by muse, mutect2, varscan2
- RUNDC1 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs750660231, COSV100865763; called by muse, mutect2, varscan2
- SALL3 | c.2990G>A p.R997H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs775526121; called by muse, mutect2
- SBF1 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs370145179; called by muse, mutect2, varscan2
- SCYL3 | c.1840C>T p.P614S (on ENST00000367770; = p.P560S on NM_020423.7) | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV99609295; called by muse, mutect2
- SGIP1 | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs753349434, COSV99390222; called by muse, mutect2, varscan2
- SI | c.5124G>A p.M1708I | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV100013647; called by muse, mutect2
- SLC26A7 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99402393; called by muse, mutect2, varscan2
- SLC26A9 | c.1756C>G p.L586V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.766); catalogued as COSV100535928; called by muse, mutect2, varscan2
- SLC38A4 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.735); catalogued as COSV56972601; called by muse, mutect2
- STAM | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV101097927; called by muse, mutect2, varscan2
- TCP11L2 | c.1274C>G p.S425* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | catalogued as COSV100135135, COSV54430002; called by muse, mutect2, varscan2
- TEDC2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV53540056; called by muse, mutect2
- TIMP3 | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV56667079; called by muse, mutect2, varscan2
- TJP3 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV99515680; called by muse, varscan2
- TLR3 | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1334760545, COSV57167336; called by muse, mutect2, varscan2
- TMEM94 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.201); catalogued as COSV100050047; called by muse, mutect2, varscan2
- TTC19 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV99889930; called by muse, mutect2, varscan2
- TTC25 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV101102850; called by muse, mutect2, varscan2
- UTRN | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100839453; called by muse, mutect2, varscan2
- VPS13D | c.11014G>A p.A3672T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99165359; called by muse, mutect2, varscan2
- VPS13D | c.11824G>C p.E3942Q | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50634512, COSV99165361; called by muse, mutect2
- WAC | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.342); catalogued as COSV100610837, COSV100611167; called by muse, mutect2, varscan2
- ZC3H7A | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100865437; called by muse, mutect2
- ZNF101 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs373338300; called by muse, mutect2, varscan2
- ZNF526 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs371341318; called by muse, mutect2, varscan2
- ZNF676 | c.460T>C p.F154L (on ENST00000650058; = p.F122L on NM_001001411.3) | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV101236086; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.535C>G p.Q179E | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.365); catalogued as COSV100008333; called by muse, mutect2
- ZNF750 | c.650_651del p.E217Vfs*4 | Frame Shift Del (DEL) | VAF 24/43 reads (56%) | called by pindel, varscan2
- ABCA13 | c.1785C>T p.L595= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs765630285, COSV101329900; called by muse, mutect2, varscan2
- APOA4 | c.537G>A p.L179= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs750251073, COSV63361391; called by muse, mutect2, varscan2
- ATP7B | c.522C>G p.V174= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99665963; called by muse, mutect2, varscan2
- BRINP1 | c.855C>T p.I285= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV56300733, COSV99774188; called by muse, mutect2, varscan2
- CCDC150 | c.1860G>C p.L620= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV55880481, COSV99776414; called by muse, mutect2, varscan2
- CCNF | c.939G>A p.L313= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV53543217; called by muse, mutect2, varscan2
- CCT5 | c.1155T>A p.I385= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99725057; called by muse, mutect2, varscan2
- CD48 | c.186C>T p.F62= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs200699471; called by muse, mutect2, varscan2
- CHRM1 | c.501G>A p.L167= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100186064; called by muse, mutect2, varscan2
- CLCN2 | c.817C>A p.R273= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV55603482, COSV99658152; called by muse, mutect2, varscan2
- CNOT1 | c.1803C>T p.L601= | Silent (SNP) | VAF 33/161 reads (20%) | catalogued as rs753143496, COSV100408384; called by muse, mutect2, varscan2
- DOCK5 | c.1701C>T p.H567= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs777937928, COSV99375893; called by muse, mutect2, varscan2
- FAXC | c.690G>A p.L230= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV101067022, COSV67603384; called by muse, mutect2, varscan2
- FBXO31 | c.1551G>A p.R517= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV100291218; called by muse, mutect2, varscan2
- FBXO41 | c.834G>A p.V278= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99720809; called by muse, mutect2, varscan2
- FLRT2 | c.1671C>T p.V557= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100419918; called by muse, mutect2, varscan2
- GCNT2 | c.846C>T p.L282= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs780096446, COSV101097096; called by muse, mutect2
- GRIK2 | c.1836C>T p.F612= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV100022366, COSV104405831; called by muse, mutect2, varscan2
- IFT172 | c.618A>G p.A206= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99561628; called by muse, mutect2, varscan2
- KCNN3 | c.1359G>A p.T453= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs370594487, COSV55227060; called by muse, mutect2, varscan2
- LAIR2 | c.318C>A p.P106= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100003124, COSV56621632; called by muse, mutect2, varscan2
- LILRA6 | c.426C>G p.L142= | Silent (SNP) | VAF 38/313 reads (12%) | called by muse, mutect2, varscan2
- MACF1 | c.16521G>A p.K5507= (on ENST00000372915; = p.K3549= on NM_012090.5) | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV99240785; called by muse, mutect2, varscan2
- MUC16 | c.27768C>A p.I9256= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV101197795; called by muse, mutect2, varscan2
- NOS1 | c.1920C>T p.I640= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs202177894, COSV100499929, COSV57609344; called by muse, mutect2, varscan2
- OR8I2 | c.813G>A p.Q271= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100135815; called by muse, mutect2, varscan2
- PCDH7 | c.2421G>A p.T807= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs758303214; called by muse, mutect2
- PCDHGA6 | c.2289G>A p.S763= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as COSV99529287; called by muse, mutect2, varscan2
- RGS1 | c.507G>A p.T169= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs749651216, COSV66505957; called by muse, mutect2, varscan2
- RGS19 | c.417G>A p.A139= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs529223539, COSV100180579; called by muse, mutect2, varscan2
- RNF43 | c.555G>A p.R185= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV101348331, COSV101348448; called by muse, mutect2, varscan2
- SH3D19 | c.2190G>A p.P730= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs747615999, COSV58791974; called by muse, mutect2, varscan2
- SI | c.3948G>A p.Q1316= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV100013649, COSV52269620; called by muse, mutect2
- ST3GAL6 | c.679C>A p.R227= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs1211430328, COSV99504420; called by muse, mutect2, varscan2
- TAF2 | c.1458G>A p.Q486= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV65419501; called by muse, mutect2, varscan2
- TEAD3 | c.810G>A p.Q270= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100132254; called by mutect2, varscan2
- TRIM42 | c.2091A>G p.V697= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99647900; called by muse, mutect2
- TRPM5 | c.2121G>A p.P707= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs752519920, COSV50220118; called by muse, mutect2, varscan2
- TSSC4 | c.153G>A p.P51= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs911658851, COSV99329424; called by muse, mutect2
- TUSC3 | c.1032T>C p.D344= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as COSV65878214; called by muse, mutect2, varscan2
- USH2A | c.2955C>T p.C985= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100228182; called by muse, mutect2, varscan2
- ZNF302 | c.858G>A p.G286= (on ENST00000627982; = p.G207= on NM_018443.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 9/124 reads (7%) | catalogued as COSV101416427; called by muse, mutect2
- SNORA60 | n.113C>T | RNA (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
